MMRF case MMRF_2076 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0bce1225-a86e-40a2-95e4-2dd2096df43e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.1 years (26,338 days); ISS stage: II; Days to last known disease status: 999 days (2.7 years); Days to last follow up: 999 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 42 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 124 days; Days to treatment end: 124 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 125 days; Days to treatment end: 125 days.
   Treatment given: Therapeutic agents: Daratumumab + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 943 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): M Protein 2.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.556 mg/dL; Immunoglobulin G 41.3 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 4.12 µg/mL; Hemoglobin 5.95 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 304 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 39.8 g/L; Total Protein 8.8 g/dL; Glucose 8.47 mmol/L.
- Day 74 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Immunoglobulin G 3.88 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 345 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 9.13 mmol/L.
- Day 179 (ECOG 1): Hemoglobin 5.7 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 297 ×10⁹/L.
- Day 292 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.32 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.85 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 7.1 mmol/L.
- Day 368 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.36 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.57 g/L; Immunoglobulin M 1.6 g/L; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 7.43 mmol/L.
- Day 459 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 4.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.48 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 1.87 g/L; Immunoglobulin M 2.05 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 8.47 mmol/L.
- Day 551 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 2.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.63 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 1.18 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.5 mmol/L; Albumin 47 g/L; Total Protein 7.3 g/dL; Glucose 7.21 mmol/L.
- Day 642 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 3.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.52 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 2.03 g/L; Immunoglobulin M 1.17 g/L; Beta 2 Microglobulin 3.7 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 8.31 mmol/L.
- Day 735 (ECOG 2): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.86 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 1.99 g/L; Immunoglobulin M 0.78 g/L; Lactate Dehydrogenase 11.9 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 6.77 mmol/L.
- Day 788 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.86 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 1.9 g/L; Immunoglobulin M 2.39 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 14.1 mmol/L.
- Day 921 (ECOG 2): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.34 mg/dL; Immunoglobulin G 15.2 g/L; Immunoglobulin A 1.52 g/L; Immunoglobulin M 0.68 g/L; Lactate Dehydrogenase 4.55 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 10.5 mmol/L.
- Day 999 (ECOG 2): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.93 mg/dL; Immunoglobulin G 5.26 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.72 g/L; Lactate Dehydrogenase 4.02 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 1.98 mmol/L; Albumin 33 g/L; Total Protein 5.7 g/dL; Glucose 20.8 mmol/L.

Other clinical attributes
- Day -3: Weight: 75 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples)
- Sample MMRF_2076_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_2076_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
